Gene-level copy-number profile of tumor specimen ALCH-B3BU-TTP1-B from ALCHEMIST case ALCH-B3BU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen ALCH-B3BU-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e58e1ebd-0966-45d4-84f4-07d1d4c625b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3BU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/8603c200-2767-406d-86c3-2f2ee0275218

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,936; copy number 2: 54,012; copy number 3: 435; copy number 4: 1; copy number 5: 1; copy number 6: 3; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,850,950–1,859,890, 3 genes: AC025183.1, LINC02116, AC025183.2.
- chr16:8,962,706–8,966,990, 1 gene (within-gene range 0–2): AC022167.3.
- chr16:54,290,965–54,292,422, 1 gene: AC018553.1.
- chr17:1,934,677–2,025,334, 2 genes (within-gene range 0–1): RTN4RL1, AC099684.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:3,889,356–3,890,249, 1 gene, copy number 5: OR7E163P.
- chr19:1,852,382–1,863,579, 3 genes, copy number 6: AC012615.3, KLF16, AC012615.4.
- chr22:20,338,805–20,354,387, 3 genes, copy number 7 (within-gene range 2–7): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 3,936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
